Somatic mutation profile of tumor specimen MMRF_2187_1_BM_CD138pos (aliquot MMRF_2187_1_BM_CD138pos_T2_KHS5U_K14067) from MMRF case MMRF_2187, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.5 years (19,528 days).
Specimen MMRF_2187_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 941f141a-e25b-45f8-9292-ec01d72ec4cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2187_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2187_1_PB_CD3pos_C3_KHS5U_L09498; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d435062-9b12-47f6-b6c2-b7c65e7c357f

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 4, Missense Mutation 2, Frame Shift Del 1, Intron 1, Nonsense Mutation 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHD3-3 | c.30C>A p.Y10* | Nonsense Mutation (SNP) | VAF 14/14 reads (100%) | catalogued as rs781896755; called by muse, varscan2
- NADSYN1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs775486610; called by muse, mutect2, varscan2
- MROH2A | c.2730A>C p.Q910H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- SS18L2 | c.217del p.S73Qfs*13 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- APC2 | c.2166G>A p.K722= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- BRWD1 | c.-158del | 5'UTR (DEL) | VAF 15/72 reads (21%) | catalogued as rs1481534556; called by pindel, varscan2
- CYTH3 | c.449+637G>A | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs867062257; called by muse, mutect2
- FRS2 | c.*73T>C | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- NT5E | c.*164A>C | 3'UTR (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.*1656C>T | 3'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- TREM2 | c.*224C>T | 3'UTR (SNP) | VAF 9/192 reads (5%) | catalogued as rs1204635802; called by muse, mutect2
